Somatic mutation profile of tumor specimen C3L-01887-01 (aliquot CPT0104330009) from CPTAC case C3L-01887, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.0 years (17,887 days).
Specimen C3L-01887-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1725fd66-c1cb-44a9-b7ca-6d1d485a45ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01887-31 (Blood Derived Normal), aliquot CPT0105110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f56d1e8e-0130-46d6-ab42-d9401aab1e1c

The open-access MAF lists 70 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Splice Region 4, RNA 3, Intron 3, 3'UTR 2, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 258/889 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs587781525, CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.6416G>A p.R2139Q | Missense Mutation (SNP) | VAF 266/759 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs761867791, CM150462, COSV64677728; called by muse, mutect2, varscan2
- AHDC1 | c.2434G>A p.G812S | Missense Mutation (SNP) | VAF 109/310 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as COSV99899703; called by muse, mutect2, varscan2
- BASP1 | c.589C>G p.P197A | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs1000055621; called by muse, mutect2, varscan2
- CBLIF | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 230/696 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs967940953; called by muse, mutect2, varscan2
- CPZ | c.824G>A p.R275H (on ENST00000360986 / NM_001014447.3; = p.R264H on NM_003652.3) | Missense Mutation (SNP) | VAF 117/383 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749063388, COSV59921949; called by muse, mutect2, varscan2
- FOLR1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 208/589 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs753241819, COSV56616543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRRS1L | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 185/538 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764520399, COSV73746566; called by muse, mutect2, varscan2
- GDF3 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 142/429 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs755496462, COSV61712484; called by muse, mutect2, varscan2
- GGT5 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs747934573; called by muse, mutect2, varscan2
- HCAR2 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 198/569 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs931357507; called by muse, mutect2, varscan2
- HTR1D | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs757946711, COSV58447419; called by muse, mutect2, varscan2
- IL4R | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs750194290, COSV50165731; called by muse, mutect2, varscan2
- KRT12 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 128/402 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770184655, COSV52429589; called by muse, mutect2, varscan2
- LARP1 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 189/546 reads (35%) | PolyPhen benign (0); catalogued as COSV60431017; called by muse, mutect2, varscan2
- LILRA2 | c.33C>T p.L11= | Splice Region (SNP) | VAF 61/281 reads (22%) | catalogued as rs759331053, COSV99252747; called by muse, mutect2, varscan2
- LRRK1 | c.4879G>A p.V1627I | Missense Mutation (SNP) | VAF 120/456 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs778024046, COSV52626733; called by muse, mutect2, varscan2
- OR2F2 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 113/446 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs755050627; called by muse, mutect2, varscan2
- OR5I1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1565151589, COSV56887915; called by muse, mutect2, varscan2
- PLK5 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 101/444 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs943611813; called by muse, mutect2, varscan2
- PLXNC1 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 131/437 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.763); catalogued as rs746221228; called by muse, mutect2, varscan2
- PNPLA7 | c.3768C>T p.D1256= | Splice Region (SNP) | VAF 36/143 reads (25%) | catalogued as rs146885482; called by muse, mutect2, varscan2
- SORCS2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs77455588; called by muse, mutect2, varscan2
- SPTBN2 | c.774C>T p.D258= | Splice Region (SNP) | VAF 158/537 reads (29%) | catalogued as rs139240091; called by muse, mutect2, varscan2
- TBXT | c.1153C>A p.P385T | Missense Mutation (SNP) | VAF 94/172 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99753056; called by muse, mutect2, varscan2
- TMEM132C | c.3223G>A p.V1075I | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs770644110, COSV59431504; called by muse, mutect2, varscan2
- TNFRSF14 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs527252361, COSV100859178, COSV63186761, COSV63187899; called by muse, mutect2, varscan2
- TRIM63 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 192/574 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs376414719, CM146838, COSV65329492; called by muse, mutect2
- ARMH1 | c.66C>A p.N22K | Missense Mutation (SNP) | VAF 169/593 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSG4 | c.469T>A p.F157I | Missense Mutation (SNP) | VAF 213/628 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FOXA2 | c.1327T>A p.S443T (on ENST00000377115 / NM_153675.3; = p.S449T on NM_021784.5) | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRR2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 77/233 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- INTS4 | c.1515-8T>C | Splice Region (SNP) | VAF 59/346 reads (17%) | called by muse, mutect2, varscan2
- KLB | c.3112_3115del p.K1038Afs*44 | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | called by pindel, varscan2
- KMT2A | c.6440C>T p.T2147I | Missense Mutation (SNP) | VAF 111/303 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K6 | c.1652C>G p.T551R | Missense Mutation (SNP) | VAF 140/487 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MMP13 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 235/686 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPTX1 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NR1D2 | c.804_805insAAAT p.Q269Kfs*10 | Frame Shift Ins (INS) | VAF 159/532 reads (30%) | called by mutect2, pindel, varscan2
- PLXND1 | c.5347T>G p.F1783V | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- POTEB3 | c.1089A>T p.K363N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- PRAMEF1 | c.48C>G p.S16R | Missense Mutation (SNP) | VAF 143/364 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC9A4 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 163/545 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TAX1BP1 | c.677A>C p.D226A | Missense Mutation (SNP) | VAF 86/421 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TCTEX1D1 | c.79_81del p.H27del | In Frame Del (DEL) | VAF 64/235 reads (27%) | called by mutect2, pindel, varscan2
- TNRC6A | c.3605A>G p.N1202S | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- WSCD2 | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 96/337 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ABCC4 | c.81C>T p.L27= | Silent (SNP) | VAF 81/208 reads (39%) | called by muse, mutect2, varscan2
- AFF3 | c.2181C>T p.N727= | Silent (SNP) | VAF 63/179 reads (35%) | catalogued as rs1018009207, COSV57839437; called by muse, mutect2, varscan2
- ITGAX | c.2493C>T p.Y831= | Silent (SNP) | VAF 53/151 reads (35%) | catalogued as rs146985733; called by muse, mutect2, varscan2
- KL | c.2341A>C p.R781= | Silent (SNP) | VAF 228/695 reads (33%) | called by muse, mutect2, varscan2
- KLK15 | c.144C>T p.G48= | Silent (SNP) | VAF 108/453 reads (24%) | catalogued as rs371448196; called by muse, mutect2, varscan2
- MUC4 | c.5883A>T p.V1961= | Silent (SNP) | VAF 180/1177 reads (15%) | called by mutect2, varscan2
- MYH2 | c.4668T>C p.S1556= | Silent (SNP) | VAF 186/585 reads (32%) | catalogued as COSV55440957; called by muse, mutect2, varscan2
- OR2T2 | c.723G>A p.T241= | Silent (SNP) | VAF 196/858 reads (23%) | catalogued as rs771866660, COSV61617872; called by muse, varscan2
- PCDHA1 | c.2040G>A p.S680= | Silent (SNP) | VAF 166/456 reads (36%) | catalogued as COSV65377401; called by muse, mutect2, varscan2
- PCDHA8 | c.1257G>A p.S419= | Silent (SNP) | VAF 214/340 reads (63%) | catalogued as COSV65334633; called by muse, mutect2, varscan2
- PHF8 | c.1080T>C p.P360= (on ENST00000357988 / NM_001184896.1; = p.P324= on NM_015107.3) | Silent (SNP) | VAF 263/387 reads (68%) | called by muse, mutect2, varscan2
- PLXND1 | c.5346C>A p.V1782= | Silent (SNP) | VAF 70/253 reads (28%) | called by muse, mutect2, varscan2
- RYR2 | c.12534C>T p.N4178= | Silent (SNP) | VAF 142/459 reads (31%) | catalogued as rs1450929982, COSV100767427, COSV63670411; called by muse, mutect2, varscan2
- SAA2 | c.78C>T p.G26= | Silent (SNP) | VAF 218/806 reads (27%) | catalogued as rs774316977; called by muse, mutect2, varscan2
- UTS2R | c.624C>T p.H208= | Silent (SNP) | VAF 52/141 reads (37%) | called by muse, mutect2, varscan2
- AC104825.1 | n.1579G>A | RNA (SNP) | VAF 238/700 reads (34%) | catalogued as rs776034720; called by muse, mutect2, varscan2
- BOD1P2 | n.139A>G | RNA (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- GATM | c.*43G>C | 3'UTR (SNP) | VAF 124/432 reads (29%) | called by muse, mutect2, varscan2
- GRM7-AS3 | n.72+4442C>T | Intron (SNP) | VAF 84/288 reads (29%) | catalogued as rs1042379309; called by mutect2, varscan2
- IGKV1-13 | n.279T>G | RNA (SNP) | VAF 167/926 reads (18%) | catalogued as rs1242670414; called by muse, mutect2, varscan2
- MRPL54 | c.*30C>T | 3'UTR (SNP) | VAF 65/359 reads (18%) | catalogued as rs762419506; called by muse, mutect2, varscan2
- PSG1 | c.1243+351T>A | Intron (SNP) | VAF 49/243 reads (20%) | called by muse, mutect2, varscan2
- SLC1A3 | c.181+4188T>G | Intron (SNP) | VAF 99/281 reads (35%) | called by muse, mutect2, varscan2
